Surgical pathology report (de-identified scan), TCGA case TCGA-63-A5MM, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-63-A5MM-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	Squamous Cell Carcinoma, Not Otherwise Specified (NOS)
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	Other
Tumour Size (cm)	4.2999999999999998
Histology	Squamous carcinoma
Grade/Differentiation	III
Pathological T	T2a
Pathological N	N1
Clinical M	M0
VALCSG Stage	
Histology Comments	Tumour location in left upper and lower lobe.

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD O-3

Carcinoma, squamous cell NOS

807013

Site ④ Lung, upper lobe + lower lobe

C34.8

20 2/1/13

2/7/13

Tumor Malignancy History		✓

Source: NCI Genomic Data Commons file a4b4f108-5829-4975-a2de-7edc90c45889 (TCGA-63-A5MM.5174B6E7-5492-4E02-99D2-CD23D456E7F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).